TCGA case TCGA-43-6770 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/381edbe7-f391-4154-b16e-ac91d550582e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.4 years (21,683 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 653 days (1.8 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant PRAME Protein Plus AS15 Adjuvant GSK2302025A; Days to treatment start: 65 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 85 days; Disease response: Tumor Free.
- Days to follow up: 310 days; Disease response: Tumor Free.
- Days to follow up: 653 days (1.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Adjuvant Therapy.

Other clinical attributes
- DLCO (% of predicted): 59; FEV1/FVC after bronchodilator (%): 96; FEV1/FVC before bronchodilator (%): 99; FEV1 after bronchodilator (% of reference): 93; FEV1 before bronchodilator (% of reference): 97.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 34; Tobacco smoking onset year: 1977.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-43-6770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-43-6770-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 71; Percent normal cells: 0; Percent necrosis: 11; Percent stromal cells: 4; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
  Slide TCGA-43-6770-01A-01-BS1: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 77; Percent normal cells: 0; Percent necrosis: 31; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-43-6770-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-43-6770-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-43-6770-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Pulmonary function test indicator: Yes.
- Drug treatment: Pharmaceutical therapy drug name: recPRAME+AS15; Clinical trial drug classification: Antigen specific cancer immunotherapeutic therapy.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 653 days; disease-specific survival: no event (censored), 653 days; disease-free interval: no event (censored), 653 days; progression-free interval: no event (censored), 653 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-43-6770-01A-11D-1816-01): tumor purity 0.69, ploidy 1.9, whole-genome doublings 0.
